Gene-level copy-number profile of tumor specimen TCGA-32-4211-01A from TCGA case TCGA-32-4211, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.8 years (20,748 days).
Specimen TCGA-32-4211-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.1a6f1433-fdfe-4c7e-b8c0-7ad4e781de45.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-32-4211-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d4d1e65-3aa5-447a-a344-a74c892b9d41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,233; copy number 2: 46,903; copy number 3: 1,301; copy number 4: 3,043; copy number 5: 104; copy number 8: 41; copy number 9: 8; copy number 11: 86; copy number 15: 1; copy number 17: 49; copy number 18: 13; copy number 19: 7; copy number 22: 4; copy number 23: 5; copy number 29: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-32-4211-01A-01D-1224-01): tumor purity 0.65, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 326 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–58,118,070, 127 genes, copy number 8–11 (broad region; genes not listed).
- chr5:60,304,047–60,304,151, 1 gene, copy number 19: RNU6-806P.
- chr7:38,257,879–38,311,808, 8 genes, copy number 9: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr12:19,147,074–19,176,589, 2 genes, copy number 19: AC092828.1, RN7SL459P.
- chr12:39,755,025–40,106,089, 1 gene, copy number 19 (within-gene range 1–19): SLC2A13.
- chr12:40,068,243–40,068,590, 1 gene, copy number 19: RPL30P13.
- chr12:43,353,866–43,661,101, 5 genes, copy number 23: ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17.
- chr12:57,516,588–58,105,935, 44 genes, copy number 17: DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:68,686,951–68,850,686, 8 genes, copy number 29: NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:71,448,405–71,448,850, 1 gene, copy number 15: AC090116.1.
- chr12:71,754,863–71,927,248, 5 genes, copy number 17 (within-gene range 2–17): RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr12:77,775,783–77,783,576, 1 gene, copy number 22: AC138331.1.
- chr12:82,223,681–84,154,338, 13 genes, copy number 18 (within-gene range 2–18): CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3.
- chr12:84,448,625–84,672,026, 2 genes, copy number 19: AC087888.1, AC093027.1.
- chr12:85,955,666–86,838,904, 1 gene, copy number 22 (within-gene range 1–22): MGAT4C.
- chr12:86,599,578–87,042,423, 2 genes, copy number 22: AC010196.1, AC079597.1.
- chr14:21,868,839–22,531,138, 104 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,852. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
